Gene-level copy-number profile of tumor specimen ALCH-B4XC-TTP1-A from ALCHEMIST case ALCH-B4XC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.8 years (25,845 days).
Specimen ALCH-B4XC-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 02e51838-a2f0-4acd-b3a1-3a4d5965bb61.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4XC-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/4fa4bdf4-1537-4e11-b844-19aee3e16dd7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 69; copy number 1: 529; copy number 2: 55,907; copy number 3: 905; copy number 4: 482; copy number 5: 152; copy number 6: 49; copy number 7: 185; copy number 9: 22; copy number 10: 101.

Homozygous deletions (total copy number 0; autosomes only): 69 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:23,616,499–23,617,987, 1 gene (within-gene range 0–2): AC011239.2.
- chr2:26,457,203–26,558,756, 1 gene: OTOF.
- chr3:50,341,106–50,649,291, 14 genes: ZMYND10-AS1, ZMYND10, NPRL2, CYB561D2, Z84492.2, TMEM115, CACNA2D2, Z84492.1, RNA5SP131, C3orf18, HEMK1, AC096920.1, CISH, MAPKAPK3.
- chr3:52,777,595–52,835,729, 6 genes (within-gene range 0–2): ITIH1, ITIH3, ITIH4, AC006254.1, ITIH4-AS1, MUSTN1.
- chr4:49,523,648–49,523,857, 1 gene: AC119751.2.
- chr6:34,537,802–34,556,333, 1 gene: SPDEF.
- chr15:25,180,497–25,250,940, 39 genes (within-gene range 0–2): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr16:83,899,115–84,002,776, 4 genes (within-gene range 0–2): MLYCD, AC009119.2, OSGIN1, NECAB2.
- chr22:20,198,729–20,208,524, 2 genes: AC007663.2, LINC00896.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 509 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,528,745–2,801,717, 12 genes, copy number 6: HES5, AL139246.5, TNFRSF14-AS1, TNFRSF14, AL139246.2, AL139246.3, PRXL2B, MMEL1, MMEL1-AS1, TTC34, AC242022.2, AC242022.1.
- chr8:66,021,553–66,860,472, 19 genes, copy number 5 (within-gene range 2–5): DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44.
- chr8:66,767,400–66,768,005, 1 gene, copy number 5 (within-gene range 2–5): PTTG3P.
- chr8:73,290,242–73,747,708, 10 genes, copy number 7 (within-gene range 4–7): RPL7, RDH10, RDH10-AS1, AC111149.1, AC111149.2, STAU2-AS1, STAU2, AC018620.1, AC100784.1, VENTXP6.
- chr8:79,891,553–85,646,325, 96 genes, copy number 5–10 (broad region; genes not listed).
- chr8:99,873,200–102,893,864, 80 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr8:102,891,876–102,893,608, 1 gene, copy number 5 (within-gene range 3–5): AP003354.1.
- chr8:110,555,408–113,436,939, 19 genes, copy number 5–6 (within-gene range 5–9): AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2.
- chr8:115,950,511–116,403,757, 4 genes, copy number 9: LINC00536, RNA5SP276, AC090994.1, AC105177.1.
- chr8:123,178,960–123,416,350, 18 genes, copy number 9: FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6.
- chr8:124,998,497–128,564,679, 50 genes, copy number 5–10: SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr8:129,241,228–129,291,275, 3 genes, copy number 6: AC103833.2, AC103833.1, RN7SKP206.
- chr8:134,477,788–135,456,952, 18 genes, copy number 6: ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1.
- chr8:137,809,444–138,083,657, 3 genes, copy number 6: AC046195.1, AC046195.2, AC079015.1.
- chr8:140,657,900–141,195,808, 7 genes, copy number 5: PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1.
- chr8:141,968,091–145,066,685, 168 genes, copy number 7–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 529. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
